Somatic mutation profile of tumor specimen MMRF_2757_1_BM_CD138pos (aliquot MMRF_2757_1_BM_CD138pos_T1_KHS5U_L15093) from MMRF case MMRF_2757, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.6 years (23,219 days).
Specimen MMRF_2757_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41ec2735-dbc9-4da1-a618-18aaec6e361f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2757_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2757_1_PB_WBC_C3_KHS5U_L15094; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40bc9bb9-ea09-4601-be31-ac1f1e0a324b

The open-access MAF lists 128 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 32, Silent 16, Intron 11, 5'UTR 5, RNA 5, 3'Flank 3, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASMT | c.910C>T p.L304F (on ENST00000381229; = p.L332F on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201741679; called by muse, mutect2, varscan2
- CC2D1B | c.2478dup p.K827Efs*22 | Frame Shift Ins (INS) | VAF 106/173 reads (61%) | catalogued as rs760045420; called by mutect2, pindel, varscan2
- CES5A | c.810C>T p.D270= | Splice Region (SNP) | VAF 21/44 reads (48%) | catalogued as rs201974680; called by muse, mutect2, varscan2
- IGKJ4 | c.7T>A p.F3I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | PolyPhen benign (0.336); catalogued as rs191712435; called by muse, varscan2
- IGLV3-1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs560070339; called by muse, varscan2
- IGLV3-1 | c.211A>T p.K71* | Nonsense Mutation (SNP) | VAF 66/140 reads (47%) | catalogued as rs371025428; called by muse, varscan2
- KCNJ4 | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 162/359 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158591856; called by muse, mutect2, varscan2
- MAGI2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs768765357, COSV100835310; called by muse, mutect2, varscan2
- NEFM | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as rs1436315984, COSV55332117; called by muse, mutect2
- PCDHGA6 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.124); catalogued as rs377211748, COSV53954000, COSV54016321; called by muse, mutect2, varscan2
- UNC13B | c.4246G>A p.V1416M | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV61469885; called by muse, mutect2, varscan2
- ABCC8 | c.2893C>A p.L965I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ADAMTS9 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF5 | c.3643T>G p.F1215V | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADRA1B | c.622T>A p.S208T | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- AGR2 | c.358C>G p.P120A | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ARCN1 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ARSL | c.1717T>C p.C573R | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BICC1 | c.295A>C p.K99Q | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHMP4C | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CLVS2 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DMXL1 | c.3677T>C p.I1226T | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.7418G>T p.G2473V | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENAH | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FARSB | c.1504T>C p.Y502H | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FIGN | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- GRIA4 | c.874A>T p.T292S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF3C2 | c.2412T>C p.G804= | Splice Region (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- INTS6 | c.2476+1G>T p.X826_splice | Splice Site (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- KIF25 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- KRTAP19-1 | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAEL | c.1154A>C p.N385T | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEL2 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MFHAS1 | c.2353C>T p.L785F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYH7B | c.1459A>T p.I487F | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEUROG3 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NF1 | c.1854_1857del p.D618Efs*12 | Frame Shift Del (DEL) | VAF 42/48 reads (88%) | called by mutect2, pindel, varscan2
- OPRPN | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RBM27 | c.718_745del p.V240Lfs*55 | Frame Shift Del (DEL) | VAF 27/220 reads (12%) | called by mutect2, pindel
- RTL1 | c.4061A>G p.D1354G | Missense Mutation (SNP) | VAF 75/87 reads (86%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- SH3PXD2A | c.2593G>T p.V865L (on ENST00000369774 / NM_001365079.1; = p.V837L on NM_014631.2) | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SHROOM2 | c.3677_3704del p.R1226Hfs*16 | Frame Shift Del (DEL) | VAF 107/287 reads (37%) | called by mutect2, pindel, varscan2
- SINHCAF | c.261G>C p.K87N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIRPB1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 139/318 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC18A1 | c.508A>T p.M170L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SYAP1 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SYT10 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TERT | c.2711T>A p.V904E | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TMC1 | c.408A>C p.K136N | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TMEM43 | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.106); called by muse, mutect2
- TRIO | c.4519C>T p.R1507W | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.888G>T p.L296F | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- WAS | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- XPO5 | c.1088C>A p.P363Q | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ZDHHC15 | c.251A>C p.N84T | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFP62 | c.1431T>A p.Y477* (on ENST00000502412 / NM_001377944.1; = p.Y444* on NM_152283.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- ANGPTL4 | c.1137C>T p.F379= | Silent (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- ATP4A | c.2838C>G p.L946= | Silent (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- C17orf80 | c.303A>G p.E101= | Silent (SNP) | VAF 102/121 reads (84%) | called by muse, mutect2, varscan2
- C5 | c.3576G>A p.A1192= | Silent (SNP) | VAF 122/227 reads (54%) | catalogued as rs777439825, COSV99796861; called by muse, mutect2, varscan2
- CCDC168 | c.9858G>A p.K3286= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV59420019, COSV59421411; called by muse, mutect2, varscan2
- CNOT3 | c.1506G>T p.V502= | Silent (SNP) | VAF 43/161 reads (27%) | called by muse, mutect2, varscan2
- DUOX1 | c.270C>T p.A90= | Silent (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.87G>C p.V29= | Silent (SNP) | VAF 82/215 reads (38%) | catalogued as rs746214227; called by muse, mutect2, varscan2
- IRX1 | c.1287G>T p.S429= | Silent (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2, varscan2
- PRPF8 | c.4810C>T p.L1604= | Silent (SNP) | VAF 97/104 reads (93%) | called by muse, mutect2, varscan2
- PRRT4 | c.804G>A p.R268= | Silent (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- PRSS16 | c.1095G>C p.L365= | Silent (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- SCART1 | c.534T>A p.P178= | Silent (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- TAS1R1 | c.963G>T p.V321= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- TREX2 | c.813G>A p.P271= (on ENST00000334497; = p.P228= on NM_080701.3) | Silent (SNP) | VAF 54/86 reads (63%) | catalogued as rs988426315; called by muse, mutect2, varscan2
- UNC80 | c.3171C>T p.H1057= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV55906336; called by muse, mutect2, varscan2
- AC009729.1 | n.1049C>G | RNA (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- AC073140.1 | n.94dup | RNA (INS) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- ACOT9 | c.704-183A>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- ADRA1A | c.-13C>A | 5'UTR (SNP) | VAF 76/127 reads (60%) | called by muse, mutect2, varscan2
- API5 | c.*236T>G | 3'UTR (SNP) | VAF 148/331 reads (45%) | called by muse, mutect2, varscan2
- BRWD3 | c.*1234T>C | 3'UTR (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- C11orf87 | c.*1970A>G | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- C1QTNF3 | c.*593C>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- C8orf34 | c.1105+1371T>A | Intron (SNP) | VAF 104/183 reads (57%) | called by muse, mutect2, varscan2
- CARF | c.*2316T>C | 3'UTR (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- CBX8 | c.*2426G>T | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- CDH11 | c.-319C>T | 5'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- CEP43 | c.*1329G>A | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- CEP85L | c.1020+44A>G | Intron (SNP) | VAF 70/75 reads (93%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.1071+1497A>G | Intron (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2
- COL6A4P1 | n.186C>T | RNA (SNP) | VAF 70/137 reads (51%) | catalogued as rs1211217181; called by muse, mutect2, varscan2
- CSF2RB | c.*1874_*1877del | 3'UTR (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- CSNK2A1 | c.*324C>A | 3'UTR (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- ENPEP | c.*2551del | 3'UTR (DEL) | VAF 46/94 reads (49%) | catalogued as rs1211711558; called by mutect2, varscan2
- ENY2 | c.229+44G>A | Intron (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- FAS | c.*1460G>T | 3'UTR (SNP) | VAF 57/110 reads (52%) | catalogued as rs9658777; called by muse, mutect2, varscan2
- GASK1B | c.910+627C>T | Intron (SNP) | VAF 17/109 reads (16%) | catalogued as rs950758915; called by muse, mutect2, varscan2
- GRID1 | c.*1864T>C | 3'UTR (SNP) | VAF 60/128 reads (47%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.*2414T>C | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- IQGAP1 | c.*1501C>T | 3'UTR (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- KCNT1 | c.378-85C>T | Intron (SNP) | VAF 58/125 reads (46%) | catalogued as rs959887873, COSV53707415; called by muse, mutect2, varscan2
- MAGEC3 | c.1729-17T>A | Intron (SNP) | VAF 82/219 reads (37%) | catalogued as COSV53578181; called by muse, mutect2, varscan2
- MSRB3 | c.*1800dup | 3'UTR (INS) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- MYRFL | c.*260G>A | 3'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2
- OR10AG1 | chr11:55967466 T>C | 3'Flank (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- OR2L6P | n.407G>A | RNA (SNP) | VAF 64/245 reads (26%) | called by muse, mutect2, varscan2
- PCDH15 | c.*3548T>G | 3'UTR (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- PCDH9 | c.*1007C>T | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- PKP4 | chr2:158682317 G>A | 3'Flank (SNP) | VAF 43/142 reads (30%) | called by muse, mutect2, varscan2
- PTPN18 | c.*307C>A | 3'UTR (SNP) | VAF 85/171 reads (50%) | called by muse, mutect2, varscan2
- PTPN18 | c.*308T>C | 3'UTR (SNP) | VAF 84/168 reads (50%) | called by muse, mutect2, varscan2
- RNASEL | c.-102A>G | 5'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- RPL37 | c.*3433T>A | 3'UTR (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.*5375G>A | 3'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- SCN7A | c.*45dup | 3'UTR (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.*134A>C | 3'UTR (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- SLC18A1 | c.1147-414A>T | Intron (SNP) | VAF 49/143 reads (34%) | called by muse, mutect2, varscan2
- SLC35E3 | c.-167T>G | 5'UTR (SNP) | VAF 57/108 reads (53%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143623587 A>G | 3'Flank (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+55106C>T | Intron (SNP) | VAF 31/188 reads (16%) | called by muse, mutect2, varscan2
- THSD7A | c.*822G>A | 3'UTR (SNP) | VAF 18/59 reads (31%) | catalogued as rs770378544; called by muse, mutect2, varscan2
- TMX4 | c.*1862C>A | 3'UTR (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- TNIK | c.*49del | 3'UTR (DEL) | VAF 97/339 reads (29%) | called by mutect2, pindel, varscan2
- TRANK1 | c.*25A>T | 3'UTR (SNP) | VAF 37/149 reads (25%) | called by muse, mutect2, varscan2
- TRIM24 | c.*4759A>G | 3'UTR (SNP) | VAF 43/99 reads (43%) | called by muse, mutect2, varscan2
- UBR2 | c.*1867T>G | 3'UTR (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- WASHC3 | c.*142A>G | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- XG | c.*1424C>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as rs62582278, COSV66985523; called by muse, varscan2
- ZNF174 | c.-8C>T | 5'UTR (SNP) | VAF 92/225 reads (41%) | called by muse, mutect2, varscan2
- ZNF252P | n.4759A>T | RNA (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- ZSCAN2 | c.406+2276G>T | Intron (SNP) | VAF 26/178 reads (15%) | called by muse, mutect2, varscan2
